Surgical pathology report (de-identified scan), TCGA case TCGA-55-6543, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-6543-01A (Primary Tumor).

[page 1 of 3]
FINAL PATHOLOGIC DIAGNOSIS:

A. Level 10 lymph node:

Benign, hyperplasia.

B. Level 11 lymph node:

Benign, hyperplasia.

C. Right upper lobe of lung lobectomy:

Carcinoma.

Tumor characteristics:

Histologic type: Adenocarcinoma with mucinous and bronchoalveolar features.

Histologic grade: Low-grade (1/3).

Tumor site: Peripheral.

Tumor focality: Unifocal.

Tumor size: 3.0 x 2.0 x 2.0 cm.

Visceral pleural invasion: No.

Lymphovascular space invasion: Not identified.

Tumor extension: Tumor confined to lung.

Treatment effect: Not identified.

Surgical margin status:

Tumor distance from bronchial margin: 2.5 cm.

Tumor distance from parenchymal margin: 2.5 cm.

Tumor distance from pleural surface: less than 0.1 cm.

Lymph node status (utilizing all specimens submitted):

Total number of lymph nodes received: Seven.

Total number of lymph nodes containing metastatic carcinoma:

None.

Other:

Other significant findings: the frozen section diagnosis is confirmed.

pTN stage: pT1,N0.

D. Level 4 lymph node:

Benign hyperplasia.

COMMENTS:

CLINICAL HISTORY:

Preoperative Diagnosis: [REDACTED] left upper lobe mass, positive smoker, question malignancy. Please call

[page 2 of 3]
results to

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Level 10 lymph node
- B. Level 11 lymph node
- C. Right upper lobe with frozen section
- D. Level 4 lymph node

CODES:

88305

88305

88309

88331

88342

88342

88342

88342

88305

GROSS DESCRIPTION:

The specimen is received in four containers labeled with the

Container A is additionally labeled "level 10 lymph node" and contains a 2.0 x 1.0 x 0.5 cm, yellow-tan, firm, fatty nodule consistent with possible lymph node. The specimen is bisected to reveal a black, anthracotic cut surface. The specimen is entirely submitted in cassette A labeled {

Container B is additionally labeled "level 11 lymph nodes" and contains a 1.5 x 1.5 x 1.0 cm, tan-brown, rubbery nodule bisected to reveal a gray-black anthracotic cut surface. The specimen is entirely submitted in cassette B labeled

Container C is additionally labeled "right upper lobe" and contains a 13.0 x 10.5 x 4.0 cm, purple-pink, moderately anthracotic lung lobe featuring an 8.5 cm in length stapled parenchymal margin as well as an additional stapled vascular margin and stapled bronchial margin, each measuring 0.5 cm in length by 1.5 cm in diameter. The bronchus is opened to reveal a yellow-tan striated endothelium. No discrete masses are identified. The stapled line is removed and the underlying parenchyma is inked black. The specimen is serially sectioned to reveal a 3.0 x 2.0 x 2.0 cm, yellow-tan, glistening, mucoid mass that abuts the inked pleura and approaches to within 2.5 cm of the vascular, bronchial and inked parenchymal margins. The remainder of the cut surface is beefy red and congested with no additional lesions. Five possible anthracotic parabronchial lymph nodes are identified ranging from 0.3 to 0.5 cm in greatest dimension. A representative section of the mass is

[page 3 of 3]
submitted for frozen section with the residual entirely resubmitted for permanent section in cassette C1 labeled

Additional representative sections are submitted in cassettes C2-10 designated as follows: C2 bronchial and vascular margin, en face; C3 inked parenchymal margin, perpendicular; C4 through 8 entire mass to inked pleura, perpendicular; C9 uninvolved parenchyma; C10 five whole possible lymph nodes. Additionally, a yellow and green cassette are submitted for genomic research, each labeled

Container D is additionally labeled "level 4 lymph node" and contains a 2.8 x 1.7 x 1.2 cm, yellow-tan fibrofatty soft tissue. On section and palpation, ill defined areas of black discoloration are identified, however no discrete lymph nodes are palpated. The specimen is entirely submitted in cassettes D1-2 labeled

INTRA-PROCEDURE CONSULTATION:

Frozen section diagnosis part C: Consistent with adenocarcinoma with mucinous features. Per

MICROSCOPIC DESCRIPTION:

The frozen section diagnosis is confirmed. The neoplastic cells are CK7 and TTF positive as well as CK 20 and CDX2 negative.

Source: NCI Genomic Data Commons file 69d475da-9e6d-4a2f-9511-9ca8f57868a7 (TCGA-55-6543.B1B81957-278C-4C30-AF49-821AB7E0429C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).